CCDI case PBBUPV — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/57b48504-b7d4-48dc-af8b-039ec5b7a46b

Demographics
Sex at birth: male; Ethnicity: hispanic or latino; Vital status: Alive.

Diagnoses (1)
1. Oligoastrocytoma: ICD-O-3 morphology code: 9382/3; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 1.0 years (369 days).

Biospecimens (3 samples)
- Sample 0DIMVM: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DIMWH: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DIMX6: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
